Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I7-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

1CD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9

3/12/11 *lw*

Clinical History and Impression:

year old male presents with metastatic melanoma right thigh (T4, N3, M0, Stage IV), here for resection. melanoma removed from mid sternal/xiphoid area. treated for local recurrence with wide excision. treated with wide excision for second local recurrence of the chest. Allergic to penicillin.

Specimen(s) Received:

- 1: SOFT TISSUE MASS RIGHT FOREHEAD
- 2: METASTATIC MELANOMA RIGHT MEDIAL THIGH

FINAL DIAGNOSIS

1) SKIN, RIGHT FOREHEAD, EXCISION:

- FIBROSIS AND MIXED INFLAMMATION WITH EOSINOPHILS AND SLIGHTLY INCREASED VESSELS (SEE NOTE)

Note: The findings would be compatible with angiolymphoid hyperplasia with eosinophilia. Clinical correlation is recommended.

2) SOFT TISSUE, RIGHT MEDIAL THIGH, EXCISION:

- CONSISTENT WITH METASTATIC MELANOMA (SEE NOTE)

Note: Within the soft tissue, there are nodules of atypical cells (positive with S-100), with many foci of necrosis. Tumor cells focally extend to the margins.

Pathologist: *[Signature]* M.D.
* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description: *[Signature]* D.O. P.A.

1) Received fresh, labeled with the patient's name, unit number, and "soft tissue mass, right forehead", is a unoriented skin ellipse (2.7 x 1.4 x 0.6 cm). The epidermal surface of the hair-bearing skin is grossly unremarkable. There is no evidence

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

of a pigmented lesion. The resection margin is inked in black, the specimen is serially-sectioned and submitted as follows: block 1= tips; blocks 2-3= remainder of specimen, serially-sectioned.

2)-Received fresh, labelled with the patient's name, MR# and "metastatic melanoma right medial thigh", is a 10.5 x 7 x 6.5 cm tumor mass, containing skeletal muscle. The specimen is unoriented. The specimen is inked orange. The original tumor mass was removed by the surgeons, and the rest of the specimen is inked blue, corresponding to the surgical margin. Gross photos are taken. The specimen is serially-sectioned and representative sections are submitted in cassettes 1-5.

Summary of Stains Performed and Reviewed

	Count
Melan-A *	1
S-100 Protein *	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the ~~designated~~ Pathology Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

		Block Detail	
	# Blocks	Designation	Description
Part 1) SOFT TISSUE MASS RIGHT FOREHEAD	3	(Undes)	(3)
Part 2) METASTATIC MELANOMA RIGHT MEDIAL	5	SOFT TISSUE (5)	(No Description) melanoma
Total:	8		

END OF REPORT

Source: NCI Genomic Data Commons file 2f622abe-7cbf-476b-879c-dd422c07f06a (TCGA-DA-A1I7.430B9506-DAC2-472F-B051-3B542F2D5243.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).